Gene-level copy-number profile of tumor specimen TCGA-55-7727-01A from TCGA case TCGA-55-7727, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.0 years (25,929 days).
Specimen TCGA-55-7727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.52452f43-e835-49d8-8454-ad1cfd90997d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7727-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ec77c061-8388-4eb1-9e90-e6689f86b690

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,592; copy number 2: 13,111; copy number 3: 16,072; copy number 4: 21,328; copy number 5: 6,130; copy number 6: 350; copy number 7: 116; copy number 8: 143; copy number 9: 73; copy number 10: 811; copy number 12: 92.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7727-01A-11D-2166-01): tumor purity 0.56, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 976 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 10 (broad region; genes not listed).
- chr14:28,673,241–47,802,201, 266 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,585. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
